Surgical pathology report (de-identified scan), TCGA case TCGA-22-4613, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4613-01A (Primary Tumor).

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Left upper lobe lung (100 grams, 15.0 x 7.5 x 5.0 cm), superior mediastinal (left lower paratracheal), aortic (subaortic, para-aortic), inferior mediastinal (subcarinal, left pulmonary ligament) and N1 (interlobar, lobar) lymph nodes.

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma, forming a 2.3 x 2.0 x 1.3 cm nodule in the left upper lobe. The pleura is uninvolved. The tumor is 4.5 cm from the bronchial margin. The bronchial resection margin and multiple (4) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, superior and inferior mediastinal, aortic, N1, excision: Multiple (2 left lower paratracheal, 6 subaortic, 1 para-aortic, 14 subcarinal, 2 left pulmonary artery, 1 interlobar, 1 lobar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 70d11cfb-a290-4849-a63e-a75b9a379a2d (TCGA-22-4613.BBB6127C-7368-415D-B984-65E21E23C03A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).